Somatic mutation profile of tumor specimen 0D8XGK from CCDI case PBBIDB, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Glioma, malignant; Tissue or organ of origin: Overlapping lesion of brain; Age at diagnosis: 4.1 years (1,501 days).
Specimen 0D8XGK: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0ae35cb8-5ba8-4a3a-9970-86e1cd2c907e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0D8XGM (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c3a26785-cc23-4dcd-8c2d-f2521915a804

The open-access MAF lists 14 somatic variants for this specimen: 11 protein-altering or splice-affecting, 2 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 8, Nonsense Mutation 2, Silent 2, In Frame Del 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3R1 | c.1358_1360del p.N453del (on ENST00000521381 / NM_181523.3; = p.N183del on NM_181504.4) | In Frame Del (DEL) | VAF 57/308 reads (19%) | hotspot (GDC flag); called by mutect2, varscan2
- TP53 | c.1024C>T p.R342* | Nonsense Mutation (SNP) | VAF 85/539 reads (16%) | hotspot (GDC flag); catalogued as rs730882029, CM004908, COSV52665487; ClinVar: pathogenic; called by muse, mutect2, varscan2
- BTBD3 | c.982G>C p.D328H | Missense Mutation (SNP) | VAF 76/866 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as COSV54778355; called by muse, mutect2
- MCM2 | c.247G>A p.A83T | Missense Mutation (SNP) | VAF 58/454 reads (13%) | SIFT tolerated (0.54); PolyPhen benign (0.129); catalogued as rs768536290, COSV54036545; called by mutect2, varscan2
- NOS1 | c.1708C>A p.P570T | Missense Mutation (SNP) | VAF 45/402 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV57622271; called by muse, mutect2, varscan2
- SI | c.4510C>T p.R1504* | Nonsense Mutation (SNP) | VAF 25/504 reads (5%) | catalogued as rs1164456060, COSV52265207; called by muse, mutect2
- CD46 | c.1164A>T p.K388N | Missense Mutation (SNP) | VAF 26/796 reads (3%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0.007); called by muse, mutect2
- CMPK1 | c.160C>T p.R54C | Missense Mutation (SNP) | VAF 28/461 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.293); called by muse, mutect2
- CRYBB3 | c.29A>G p.Q10R | Missense Mutation (SNP) | VAF 49/367 reads (13%) | SIFT deleterious (0.05); PolyPhen benign (0.325); called by muse, mutect2, varscan2
- DUSP15 | c.655A>T p.I219F | Missense Mutation (SNP) | VAF 14/368 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.329); called by muse, mutect2
- NRP2 | c.430A>G p.T144A | Missense Mutation (SNP) | VAF 68/676 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.076); called by muse, mutect2, varscan2
- BCOR | c.1242G>A p.A414= | Silent (SNP) | VAF 94/312 reads (30%) | catalogued as rs146423227; called by muse, mutect2, varscan2
- EIF1AY | c.177C>T p.C59= | Silent (SNP) | VAF 26/384 reads (7%) | called by muse, mutect2
- LARP4 | c.1334+88A>C | Intron (SNP) | VAF 4/38 reads (11%) | called by mutect2, varscan2
